Somatic mutation profile of tumor specimen TCGA-D3-A3C6-06A (aliquot TCGA-D3-A3C6-06A-12D-A196-08) from TCGA case TCGA-D3-A3C6, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 57.9 years (21,160 days).
Specimen TCGA-D3-A3C6-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fe52ca8-563a-4ed0-a842-8cf837c198c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A3C6-10A (Blood Derived Normal), aliquot TCGA-D3-A3C6-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/055c56ef-c4fa-44f8-b79d-01754892218c

The open-access MAF lists 126 somatic variants for this specimen: 78 protein-altering or splice-affecting, 46 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 46, Nonsense Mutation 4, Frame Shift Del 2, 5'UTR 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- GCK | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 151/412 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs193922317, CM970635, COSV60786559; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.406T>C p.C136R | Missense Mutation (SNP) | VAF 41/56 reads (73%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs786201044, CM004336, COSV100911109, COSV64289087; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC5 | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV55588929; called by muse, mutect2, varscan2
- ADGRL3 | c.2804A>G p.K935R (on ENST00000506720 / NM_001322402.2; = p.K867R on NM_015236.6) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.446); catalogued as COSV72230222; called by muse, mutect2, varscan2
- AGAP1 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 65/79 reads (82%) | SIFT tolerated (0.05); PolyPhen benign (0.198); catalogued as rs773738495, COSV58323249; called by muse, mutect2, varscan2
- AIPL1 | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as CM167090, COSV100006183, COSV51506645, COSV51506697; called by muse, mutect2, varscan2
- ATP13A5 | c.2039A>T p.K680I | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.285); catalogued as COSV60868216; called by mutect2, varscan2
- CATSPERB | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 94/232 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV56425024; called by muse, mutect2, varscan2
- CDR1 | c.617G>A p.W206* | Nonsense Mutation (SNP) | VAF 81/107 reads (76%) | catalogued as rs780819654, COSV65164090; called by muse, mutect2, varscan2
- CENPE | c.5360A>G p.Q1787R | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV54379581; called by muse, mutect2, varscan2
- CFAP47 | c.1762C>T p.P588S | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52883269; called by muse, mutect2, varscan2
- CFI | c.1637G>T p.W546L | Missense Mutation (SNP) | VAF 127/321 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121964915, CM041381, COSV67098325, COSV67098805, COSV67099346; called by muse, mutect2, varscan2
- COL1A1 | c.4256C>T p.T1419I | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1324048814, COSV56803811; called by muse, mutect2, varscan2
- COL4A2 | c.3677G>A p.G1226E | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64627159; called by muse, mutect2, varscan2
- COLGALT1 | c.606G>C p.W202C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53108451; called by muse, varscan2
- CPQ | c.338G>T p.W113L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55136723; called by mutect2, varscan2
- CRISP2 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as rs1210469215, COSV59254157; called by muse, mutect2, varscan2
- CRYM | c.751C>A p.Q251K | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV54830575; called by mutect2, varscan2
- CYP4F3 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.247); catalogued as rs200137515, COSV55408938; called by muse, mutect2, varscan2
- DLGAP5 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.061); catalogued as rs372521527, COSV55962857; called by muse, mutect2, varscan2
- EPPIN | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60548329; called by muse, mutect2, varscan2
- FAM47A | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 45/63 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV60500128; called by muse, mutect2, varscan2
- FBN3 | c.4031C>T p.S1344F | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1334277627, COSV54458252; called by muse, mutect2, varscan2
- FCRL1 | c.886G>A p.V296M | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV63824711; called by muse, mutect2, varscan2
- GALNT1 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 53/75 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52451825; called by muse, mutect2, varscan2
- GALNT15 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT tolerated (0.11); PolyPhen benign (0.433); catalogued as COSV60216487; called by muse, mutect2, varscan2
- GGT6 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.083); catalogued as rs866581229, COSV54596585; called by muse, mutect2, varscan2
- GK2 | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62626519; called by muse, mutect2, varscan2
- GPR65 | c.210G>A p.W70* | Nonsense Mutation (SNP) | VAF 58/142 reads (41%) | catalogued as COSV50862511; called by muse, mutect2, varscan2
- GYS1 | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.917); catalogued as COSV54402263; called by muse, mutect2, varscan2
- HIF3A | c.1033G>A p.E345K (on ENST00000377670 / NM_152795.4; = p.E276K on NM_022462.4) | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV52197427; called by muse, mutect2, varscan2
- IPO4 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs754574474, COSV55778933, COSV55779068; called by mutect2, varscan2
- IQGAP1 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as COSV51583922; called by muse, mutect2, varscan2
- IQSEC2 | c.2173C>T p.P725S (on ENST00000642864 / NM_001111125.3; = p.P520S on NM_015075.2) | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT tolerated (0.1); PolyPhen benign (0.31); catalogued as COSV64724801; called by muse, varscan2
- JAKMIP1 | c.1550G>T p.R517M | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV51527768; called by mutect2, varscan2
- KIF21B | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100144711, COSV59755860; called by muse, mutect2, varscan2
- KMT2C | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 26/504 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.722); catalogued as COSV100067419, COSV51424355; called by muse, mutect2
- KRTAP10-11 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV58177571; called by mutect2, varscan2
- LRBA | c.401T>C p.V134A | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV63953188; called by muse, mutect2, varscan2
- LRRC28 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 36/102 reads (35%) | catalogued as COSV57336885; called by muse, mutect2, varscan2
- LRRN2 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.625); catalogued as rs1244068109, COSV65783539; called by muse, mutect2, varscan2
- LTB | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.157); catalogued as COSV53000990; called by muse, mutect2, varscan2
- MADD | c.4516C>A p.Q1506K | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as COSV60622854; called by muse, mutect2, varscan2
- MANSC1 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67110920; called by muse, mutect2, varscan2
- MMP2 | c.835C>T p.L279= | Splice Region (SNP) | VAF 9/23 reads (39%) | catalogued as COSV54600483; called by muse, mutect2, varscan2
- MUC16 | c.12881C>T p.S4294F | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.223); catalogued as COSV67455835; called by muse, mutect2, varscan2
- MUC5B | c.14966C>T p.S4989F | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs1490349534, COSV71591319; called by mutect2, varscan2
- NAP1L2 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV65172238; called by muse, mutect2, varscan2
- NAV1 | c.5266C>T p.R1756W | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55215757; called by muse, mutect2, varscan2
- NELL2 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as rs369537621; called by muse, mutect2, varscan2
- NOS3 | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.858); catalogued as COSV52488621; called by mutect2, varscan2
- NOX1 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 40/48 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866136739, COSV54194084; called by muse, mutect2, varscan2
- NRXN3 | c.2204G>A p.R735H (on ENST00000335750 / NM_001330195.2; = p.R362H on NM_004796.6) | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777228955, COSV59737828; called by mutect2, varscan2
- OR2L3 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs756449207, COSV63454367; called by muse, mutect2, varscan2
- OR5K3 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as rs774041879, COSV67349886; called by muse, mutect2, varscan2
- PCDHB2 | c.182T>C p.L61P | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52029255, COSV52031580; called by muse, mutect2, varscan2
- PCDHB4 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.068); catalogued as COSV99521968; called by muse, mutect2, varscan2
- PEAR1 | c.4T>A p.S2T | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV52772398; called by muse, mutect2, varscan2
- PEX5L | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs143237596; called by muse, mutect2, varscan2
- PRMT8 | c.38G>A p.R13K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.084); catalogued as COSV66890556, COSV66893301; called by muse, mutect2, varscan2
- PSEN2 | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV60915593; called by muse, mutect2, varscan2
- PSMC2 | c.1057C>T p.H353Y | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV53007136; called by muse, mutect2, varscan2
- PTPN5 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as rs748561321, COSV60032927; called by muse, mutect2, varscan2
- PTPRT | c.1757T>A p.I586N | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV61974580; called by muse, mutect2, varscan2
- SALL4 | c.2113T>A p.S705T | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV53851478; called by mutect2, varscan2
- SERPINA3 | c.988C>T p.Q330* | Nonsense Mutation (SNP) | VAF 30/74 reads (41%) | catalogued as COSV67585839; called by muse, varscan2
- SLC4A10 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as COSV55773994; called by muse, mutect2, varscan2
- TBC1D10C | c.1289G>A p.G430E | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1190199090, COSV56702452; called by muse, mutect2, varscan2
- TMEM225 | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.09); catalogued as COSV66693077; called by muse, mutect2, varscan2
- USP6 | c.3545G>A p.G1182E | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.63); catalogued as COSV51479996; called by muse, mutect2, varscan2
- XIRP2 | c.1040C>T p.S347F (on ENST00000628543; = p.S522F on NM_152381.6) | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54693768; called by muse, mutect2, varscan2
- ZNF407 | c.3112C>T p.R1038W | Missense Mutation (SNP) | VAF 58/77 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368982407; called by mutect2, varscan2
- ZNF418 | c.1837C>T p.H613Y | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs758378334, COSV68675756, COSV68676071; called by muse, mutect2, varscan2
- ZNF831 | c.4178G>A p.R1393Q | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs753837433, COSV64037136; called by muse, mutect2, varscan2
- HEATR5A | c.1454del p.T485Nfs*21 | Frame Shift Del (DEL) | VAF 66/198 reads (33%) | called by mutect2, pindel, varscan2
- PNN | c.377_398del p.R126Ifs*17 | Frame Shift Del (DEL) | VAF 48/174 reads (28%) | called by mutect2, pindel, varscan2
- TRAV36DV7 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- ABCB1 | c.3225G>A p.G1075= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV55947921; called by muse, mutect2, varscan2
- ANKLE1 | c.1236C>T p.V412= (on ENST00000394458; = p.V358= on NM_152363.6) | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV63920451; called by muse, varscan2
- ATG16L1 | c.1737C>T p.S579= (on ENST00000392017 / NM_030803.7; = p.S560= on NM_017974.4) | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV100731280; called by muse, mutect2, varscan2
- ATP9A | c.1218C>T p.L406= | Silent (SNP) | VAF 46/119 reads (39%) | catalogued as rs779610357, COSV58765250; called by muse, mutect2, varscan2
- CACNB2 | c.1938G>A p.R646= (on ENST00000324631 / NM_201596.3; = p.R591= on NM_000724.4) | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as COSV56619635; called by muse, mutect2, varscan2
- CD53 | c.357C>A p.T119= | Silent (SNP) | VAF 40/116 reads (34%) | catalogued as COSV54760880, COSV99602038; called by muse, mutect2, varscan2
- CHMP4C | c.162C>T p.A54= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV51926753; called by muse, mutect2, varscan2
- CORO1A | c.903C>T p.A301= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as rs1567377282, COSV54630956; called by muse, mutect2, varscan2
- DCST1 | c.300C>T p.I100= | Silent (SNP) | VAF 62/131 reads (47%) | catalogued as rs781314174, COSV55058347; called by muse, mutect2, varscan2
- FAM47A | c.390C>T p.P130= | Silent (SNP) | VAF 41/59 reads (69%) | catalogued as COSV100649783, COSV100650067; called by muse, mutect2, varscan2
- FBXL13 | c.1440G>A p.R480= | Silent (SNP) | VAF 44/97 reads (45%) | catalogued as rs1294206812, COSV57536942; called by muse, mutect2, varscan2
- GBP6 | c.822T>G p.T274= | Silent (SNP) | VAF 21/35 reads (60%) | catalogued as COSV65011203; called by muse, mutect2, varscan2
- GPAA1 | c.765C>T p.F255= | Silent (SNP) | VAF 61/112 reads (54%) | catalogued as COSV60155579; called by muse, mutect2, varscan2
- GRM1 | c.1062C>T p.F354= | Silent (SNP) | VAF 32/44 reads (73%) | catalogued as COSV51129025, COSV51193045; called by muse, mutect2, varscan2
- HOXC6 | c.486C>T p.F162= | Silent (SNP) | VAF 56/140 reads (40%) | catalogued as COSV54536722; called by muse, mutect2, varscan2
- ITGAL | c.2667G>A p.G889= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV63321627; called by muse, mutect2, varscan2
- KDR | c.3153G>A p.R1051= | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as rs761646311, COSV55762566, COSV99818452; called by muse, mutect2, varscan2
- LRFN1 | c.429C>T p.I143= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1260075117, COSV50434342; called by muse, mutect2, varscan2
- MAGEC1 | c.2448C>T p.S816= | Silent (SNP) | VAF 138/175 reads (79%) | catalogued as COSV53571125; called by muse, mutect2, varscan2
- MUC16 | c.30435C>T p.S10145= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs1036707018, COSV67455754; called by muse, mutect2, varscan2
- NCAPD2 | c.2763C>T p.F921= | Silent (SNP) | VAF 47/118 reads (40%) | catalogued as COSV59698822; called by muse, mutect2, varscan2
- NPAP1 | c.2697C>T p.S899= | Silent (SNP) | VAF 67/93 reads (72%) | catalogued as COSV61506047; called by muse, mutect2, varscan2
- OR51V1 | c.33G>A p.T11= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as rs550954546, COSV58314225; called by mutect2, varscan2
- OTUD6A | c.183G>A p.Q61= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as COSV57973073; called by muse, mutect2, varscan2
- PCDHB4 | c.168G>A p.G56= | Silent (SNP) | VAF 19/29 reads (66%) | catalogued as COSV99521971; called by muse, mutect2, varscan2
- PCDHB5 | c.1833C>A p.P611= | Silent (SNP) | VAF 63/82 reads (77%) | catalogued as COSV50649618, COSV50669861; called by muse, mutect2, varscan2
- PCSK5 | c.4107C>T p.V1369= | Silent (SNP) | VAF 14/16 reads (88%) | catalogued as rs780628172, COSV70448926; called by muse, mutect2, varscan2
- PIAS3 | c.285C>A p.P95= | Silent (SNP) | VAF 53/116 reads (46%) | catalogued as COSV65171184; called by mutect2, varscan2
- PLAAT5 | c.669C>T p.I223= | Silent (SNP) | VAF 47/90 reads (52%) | catalogued as rs577620226, COSV57136576, COSV57138488; called by mutect2, varscan2
- RPL8 | c.249C>T p.H83= | Silent (SNP) | VAF 111/173 reads (64%) | catalogued as rs368194465; called by muse, mutect2, varscan2
- SERINC3 | c.138C>T p.L46= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as rs1019600569, COSV54856306; called by muse, mutect2, varscan2
- SERPINB11 | c.1053G>A p.G351= | Silent (SNP) | VAF 34/40 reads (85%) | catalogued as COSV66956800; called by muse, mutect2, varscan2
- SLC22A10 | c.1380C>T p.I460= | Silent (SNP) | VAF 46/124 reads (37%) | catalogued as rs768834188, COSV60420594, COSV60420956; called by muse, mutect2, varscan2
- SNAPC2 | c.384C>T p.I128= | Silent (SNP) | VAF 76/189 reads (40%) | catalogued as COSV54490458; called by muse, mutect2, varscan2
- SPTB | c.504A>G p.E168= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs770172668, COSV67631056; called by muse, mutect2, varscan2
- TEX15 | c.810C>T p.I270= (on ENST00000256246; = p.I653= on NM_001350162.2) | Silent (SNP) | VAF 42/55 reads (76%) | catalogued as rs770815905, COSV56344916; called by mutect2, varscan2
- TRPC4 | c.1563C>T p.F521= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV58992835; called by muse, mutect2, varscan2
- TTC17 | c.2901C>T p.S967= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV50007618; called by muse, varscan2
- UBQLN3 | c.1389C>T p.S463= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as COSV61163902; called by muse, mutect2, varscan2
- UNC5D | c.2673C>T p.F891= | Silent (SNP) | VAF 45/106 reads (42%) | catalogued as rs764263396, COSV54771686; called by muse, mutect2, varscan2
- VNN3 | c.270G>A p.R90= | Silent (SNP) | VAF 21/29 reads (72%) | catalogued as COSV99258127; called by muse, mutect2, varscan2
- VWA7 | c.231C>T p.F77= | Silent (SNP) | VAF 116/229 reads (51%) | catalogued as COSV63304466; called by muse, mutect2, varscan2
- XYLT1 | c.2511C>T p.F837= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV54476086; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1122G>A p.K374= | Silent (SNP) | VAF 54/123 reads (44%) | catalogued as COSV54294895; called by muse, varscan2
- ZNF408 | c.1557C>A p.T519= | Silent (SNP) | VAF 37/71 reads (52%) | catalogued as COSV61237958; called by muse, mutect2, varscan2
- ZNF488 | c.321G>A p.R107= | Silent (SNP) | VAF 12/14 reads (86%) | called by muse, mutect2, varscan2
- MSTN | c.-1C>T | 5'UTR (SNP) | VAF 26/34 reads (76%) | catalogued as COSV99640589; called by mutect2, varscan2
- SDK1 | c.*3349G>T | 3'UTR (SNP) | VAF 84/215 reads (39%) | catalogued as COSV101268955; called by muse, mutect2, varscan2
